Somatic mutation profile of tumor specimen C3N-02270-01 (aliquot CPT0182610007) from CPTAC case C3N-02270, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 76.2 years (27,837 days).
Specimen C3N-02270-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cb26bda-65b9-447f-ad44-4d54f551f254.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02270-31 (Blood Derived Normal), aliquot CPT0182710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/002739a3-26dd-4fd8-a03d-b7aeaf0b3392

The open-access MAF lists 403 somatic variants for this specimen: 280 protein-altering or splice-affecting, 112 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 112, Nonsense Mutation 18, Intron 7, Frame Shift Ins 2, 5'UTR 2, 3'UTR 2, Frame Shift Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 122/477 reads (26%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 147/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434297, CM960995, COSV64878277; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 749/995 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS7 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 161/422 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs1479205325; called by muse, mutect2, varscan2
- ADGRF5 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 308/535 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762194348; called by muse, mutect2, varscan2
- AEN | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 215/535 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs1479727406; called by muse, mutect2, varscan2
- AGBL4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779103173, COSV61890672; called by muse, mutect2, varscan2
- ANKRD24 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 185/428 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.757); catalogued as COSV53668352; called by muse, varscan2
- ATP5F1E | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 286/499 reads (57%) | catalogued as COSV99718071; called by muse, mutect2, varscan2
- BCL11B | c.1381G>A p.D461N (on ENST00000357195 / NM_001282237.2; = p.D390N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/439 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.667); catalogued as rs776120841; called by muse, mutect2, varscan2
- BIRC6 | c.3743C>T p.S1248F | Missense Mutation (SNP) | VAF 171/452 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1415258844; called by muse, mutect2, varscan2
- BPIFB4 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747498722, COSV64950803; called by muse, mutect2, varscan2
- C4orf17 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58512938; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 150/222 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, varscan2
- CA4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 147/431 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780570538; called by muse, mutect2, varscan2
- CACNA2D1 | c.2160G>A p.W720* (on ENST00000356253 / NM_001366867.1; = p.W708* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 65/228 reads (29%) | catalogued as rs1554333964; called by muse, mutect2, varscan2
- CARD11 | c.2897T>C p.V966A | Missense Mutation (SNP) | VAF 203/499 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67796905; called by muse, mutect2, varscan2
- CD163 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.88); catalogued as rs965223448, COSV100775715, COSV63129385; called by muse, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CEP192 | c.3980C>T p.S1327F | Missense Mutation (SNP) | VAF 128/330 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58070546; called by muse, varscan2
- CFAP47 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 91/120 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52884651; called by muse, mutect2, varscan2
- CFAP74 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV54566448; called by muse, mutect2, varscan2
- CHRNB3 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 154/430 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1563616543; called by muse, varscan2
- COL21A1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280324762; called by muse, mutect2, varscan2
- COL4A6 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 206/256 reads (80%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.869); catalogued as COSV57860701; called by muse, mutect2, varscan2
- COL6A2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 193/506 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as rs374504636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV55217538; called by muse, mutect2, varscan2
- CR1 | c.5063C>T p.A1688V | Missense Mutation (SNP) | VAF 156/423 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV65459332; called by muse, mutect2, varscan2
- DACH1 | c.1936G>A p.E646K (on ENST00000619232 / NM_001366712.1; = p.E392K on NM_004392.6) | Missense Mutation (SNP) | VAF 134/685 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1179043824, COSV57503001; called by muse, varscan2
- DGLUCY | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs535969919; called by muse, mutect2, varscan2
- DHX29 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV52418207; called by muse, mutect2, varscan2
- DLGAP1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 172/454 reads (38%) | catalogued as COSV59787479; called by muse, mutect2
- DNAH14 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 139/342 reads (41%) | PolyPhen benign (0); catalogued as rs977059053; called by muse, mutect2, varscan2
- DNAH5 | c.4473G>A p.M1491I | Missense Mutation (SNP) | VAF 158/241 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV54208385; called by muse, mutect2, varscan2
- DNAH7 | c.10671G>A p.M3557I | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV56764311, COSV56765430; called by muse, mutect2, varscan2
- DNAH7 | c.7746G>A p.M2582I | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs867538625; called by muse, varscan2
- DNAJB13 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 297/545 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327469627; called by muse, mutect2, varscan2
- DSP | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 284/544 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs749422119; called by muse, mutect2, varscan2
- ERICH3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 147/409 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1388345581, COSV100443769; called by muse, mutect2, varscan2
- FAM135B | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 399/562 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1051255052; called by muse, mutect2, varscan2
- FAM20B | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 186/431 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs140406781; called by muse, mutect2, varscan2
- FAT4 | c.9619G>A p.E3207K | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868613088, COSV58715034; called by muse, mutect2, varscan2
- FBN2 | c.4096A>G p.T1366A | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs768722316; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCGR3A | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 178/1001 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs760902695, COSV63459949; called by muse, mutect2
- FLNB | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 125/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55899823; called by muse, mutect2, varscan2
- FLNC | c.8020G>A p.G2674S | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372338218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXA3 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 237/603 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs763641484, COSV56217294; called by muse, mutect2, varscan2
- GDAP2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 777/1008 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755196775, COSV101031825; called by muse, mutect2, varscan2
- GPR78 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 164/501 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV66762783; called by muse, mutect2, varscan2
- GPT | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 672/953 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs1461556728; called by muse, mutect2, varscan2
- HOXA3 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 149/398 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV57826601; called by muse, mutect2, varscan2
- HRG | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 172/475 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs1339994279, COSV51645550, COSV51647179; called by muse, mutect2, varscan2
- HRNR | c.7057G>A p.G2353S | Missense Mutation (SNP) | VAF 276/3044 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.203); catalogued as rs762159427, COSV64262187; called by muse, mutect2
- IGHV3-15 | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 119/283 reads (42%) | catalogued as rs1426478327; called by muse, mutect2, varscan2
- IL13RA2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 95/120 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs142667478; called by muse, mutect2, varscan2
- ITGAX | c.2576G>A p.W859* | Nonsense Mutation (SNP) | VAF 323/557 reads (58%) | catalogued as COSV99191537; called by muse, mutect2, varscan2
- ITIH5 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.396); catalogued as rs746984634; called by muse, mutect2, varscan2
- KCNB2 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as rs768451519, COSV73049093; called by muse, mutect2, varscan2
- KCNQ2 | c.1366G>A p.G456R (on ENST00000359125 / NM_172107.4; = p.G428R on NM_004518.6) | Missense Mutation (SNP) | VAF 424/764 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.404); catalogued as COSV100609954; called by muse, varscan2
- KCNV1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 272/483 reads (56%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs865900317, COSV52085529; called by muse, mutect2, varscan2
- KDM2B | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 182/492 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555292045, COSV100997640, COSV99058194; called by muse, mutect2, varscan2
- KIAA0586 | c.2378C>T p.P793L (on ENST00000619416 / NM_001244190.2; = p.P732L on NM_014749.5) | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1391631587; called by muse, mutect2, varscan2
- KIF2B | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 134/337 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs796994270, COSV99276257; called by muse, varscan2
- KLHL23 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 179/457 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV99775903; called by muse, mutect2, varscan2
- LAMB4 | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 143/315 reads (45%) | catalogued as rs765314600; called by muse, mutect2, varscan2
- LEXM | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 685/943 reads (73%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.622); catalogued as COSV64022330; called by muse, mutect2, varscan2
- LRRC3 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 206/518 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52400164; called by muse, mutect2, varscan2
- LSMEM2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 140/383 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); catalogued as COSV57112431; called by muse, mutect2, varscan2
- LY6K | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 131/702 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1268653589, COSV52832631; called by muse, mutect2, varscan2
- MAB21L4 | c.1279G>A p.D427N (on ENST00000388934 / NM_001085437.3; = p.D259N on NM_024861.4) | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.127); catalogued as rs866154994; called by muse, mutect2, varscan2
- MAP1B | c.4213G>A p.G1405R | Missense Mutation (SNP) | VAF 194/454 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1172597346, COSV99702889; called by muse, mutect2, varscan2
- MAP3K13 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53983072; called by muse, mutect2, varscan2
- MAP3K21 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64044668; called by muse, mutect2, varscan2
- MAP3K21 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145103476; called by muse, varscan2
- MAPT | c.1207C>T p.P403S (on ENST00000262410 / NM_001377265.1; = p.P328S on NM_016835.4) | Missense Mutation (SNP) | VAF 253/714 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV52242270; called by muse, mutect2, varscan2
- MRPL39 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750671064; called by muse, mutect2, varscan2
- MTHFR | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1557762844, COSV100928235; called by muse, mutect2, varscan2
- MUC16 | c.42083C>T p.P14028L | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as rs758986311, COSV66689571; called by muse, mutect2, varscan2
- MUC16 | c.21293C>T p.S7098F | Missense Mutation (SNP) | VAF 171/442 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as COSV101200414; called by muse, mutect2, varscan2
- MUC17 | c.10444C>T p.P3482S | Missense Mutation (SNP) | VAF 124/492 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.807); catalogued as COSV60300677; called by muse, mutect2, varscan2
- MUC3A | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 198/475 reads (42%) | SIFT deleterious, low confidence (0); catalogued as rs755539310; called by muse, mutect2, varscan2
- MYLK | c.2290del p.D764Tfs*18 | Frame Shift Del (DEL) | VAF 180/481 reads (37%) | catalogued as COSV60608714; called by mutect2, pindel, varscan2
- NAPSA | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 133/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773625617; called by muse, mutect2, varscan2
- NAV2 | c.6094G>A p.D2032N (on ENST00000396087 / NM_001244963.2; = p.D1973N on NM_145117.5) | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs150212903, COSV100217637; called by muse, mutect2, varscan2
- NCKAP1 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs772427539, COSV62940515; called by muse, varscan2
- NFASC | c.1544G>A p.R515H (on ENST00000339876 / NM_001378329.1; = p.R526H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/337 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs760519127; called by muse, mutect2, varscan2
- NUGGC | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 139/378 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV58434848; called by muse, mutect2, varscan2
- OR1N2 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 152/392 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs747683007; called by muse, mutect2, varscan2
- OR2L3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 154/442 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63454596; called by muse, varscan2
- OR2T1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 270/653 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs769406328, COSV63541354; called by muse, mutect2, varscan2
- OR51Q1 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 213/381 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56178780; called by muse, mutect2, varscan2
- OR5T3 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 189/676 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1386926733; called by muse, mutect2, varscan2
- OR5W2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 185/306 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV60615646; called by muse, mutect2, varscan2
- OR6S1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764561441; called by muse, mutect2, varscan2
- PALB2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 143/220 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); catalogued as rs1567221497, COSV55163039, COSV99848316; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PANK4 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 272/640 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750810615, COSV99615475; called by muse, mutect2, varscan2
- PARP12 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs147572823; called by muse, mutect2, varscan2
- PARP8 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV55864735; called by muse, mutect2, varscan2
- PASD1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 173/211 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64857665; called by muse, mutect2, varscan2
- PCDH8 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 232/932 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1487470169; called by muse, mutect2, varscan2
- PCDHA10 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 138/203 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56488259; called by muse, mutect2, varscan2
- PCDHB1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 197/275 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs376926724; called by muse, mutect2, varscan2
- PISD | c.508C>T p.R170W (on ENST00000439502 / NM_001326412.1; = p.R136W on NM_014338.3) | Missense Mutation (SNP) | VAF 164/434 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1424145335; called by muse, mutect2, varscan2
- PITPNM3 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 195/513 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV52593093; called by muse, mutect2, varscan2
- PLA2G4E | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763699482; called by muse, mutect2, varscan2
- POTEG | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 314/3312 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as rs768540032, COSV101611975; called by muse, mutect2
- PPARGC1B | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 245/361 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748235018; called by muse, mutect2, varscan2
- PRR36 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 232/608 reads (38%) | SIFT deleterious (0.02); catalogued as rs1044183604; called by muse, mutect2, varscan2
- PTAR1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 187/503 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV61208636; called by muse, mutect2, varscan2
- PTPN5 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 353/597 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs752519944; called by muse, mutect2, varscan2
- PTPRB | c.5144G>A p.R1715Q | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs371535586; called by muse, mutect2, varscan2
- RGS5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 153/419 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774978465, COSV58352625; called by muse, mutect2, varscan2
- RIMS4 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs867962386, COSV100865093; called by muse, mutect2, varscan2
- RNASE3 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 166/455 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs374429664; called by muse, mutect2, varscan2
- RNPS1 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.207); catalogued as rs889132486; called by muse, mutect2, varscan2
- RP1 | c.4576G>A p.E1526K | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV55110547; called by muse, mutect2, varscan2
- SALL2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 180/479 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58101971; called by muse, mutect2, varscan2
- SCN10A | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV71861189; called by muse, mutect2, varscan2
- SCN9A | c.3233C>T p.S1078L (on ENST00000303354; = p.S1067L on NM_002977.3) | Missense Mutation (SNP) | VAF 187/487 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV57601081; called by muse, mutect2, varscan2
- SERPING1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 255/496 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875169, CM096507; ClinVar: not provided; called by muse, mutect2, varscan2
- SLC13A1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs780923482, COSV52014941; called by muse, mutect2, varscan2
- SLC16A9 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs747303668, COSV68100517; called by muse, mutect2, varscan2
- SLC18A2 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 133/361 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100041770; called by muse, mutect2, varscan2
- SLC4A2 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 151/354 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs145331845; called by muse, mutect2, varscan2
- SLC6A18 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs529833536, COSV57250411; called by muse, mutect2, varscan2
- SLC6A6 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1375781532, COSV62647583; called by muse, varscan2
- SMC2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs747631183, COSV53958382; called by muse, mutect2, varscan2
- SRRM2 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 416/697 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV57074854; called by muse, mutect2, varscan2
- STAB1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 175/462 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs151153400; called by muse, mutect2, varscan2
- SUCNR1 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 134/409 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs777108323; called by muse, mutect2, varscan2
- SVEP1 | c.5789C>T p.S1930L | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs1213719259; called by muse, varscan2
- SYT3 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 239/544 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.071); catalogued as rs756693870, COSV58895486; called by muse, mutect2, varscan2
- TGM6 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 151/388 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383828; called by muse, mutect2, varscan2
- THSD4 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 160/434 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs777553782, COSV55986344; called by muse, mutect2, varscan2
- TMEM132A | c.2083G>A p.E695K (on ENST00000453848 / NM_178031.3; = p.E696K on NM_017870.4) | Missense Mutation (SNP) | VAF 176/452 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs747242321; called by muse, mutect2, varscan2
- TMEM132C | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1413359208, COSV59413018; called by muse, mutect2, varscan2
- TMEM200C | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 196/499 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs919305207; called by muse, mutect2, varscan2
- TNFRSF25 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1186336767, COSV61068592; called by muse, mutect2, varscan2
- TRPM5 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 116/544 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50144405; called by muse, mutect2, varscan2
- TTLL5 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 176/478 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54033337; called by muse, mutect2, varscan2
- TTN | c.89503G>A p.G29835R (on ENST00000591111; = p.G22411R on NM_003319.4) | Missense Mutation (SNP) | VAF 175/394 reads (44%) | PolyPhen probably damaging (1); catalogued as rs1481659337; called by muse, mutect2, varscan2
- TTN | c.27934G>A p.E9312K (on ENST00000591111; = p.E8385K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/485 reads (32%) | PolyPhen possibly damaging (0.894); catalogued as COSV60005669, COSV60041014; called by muse, mutect2, varscan2
- UGT2A1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs773148820; called by muse, mutect2, varscan2
- UTP20 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1194106783, COSV55372672; called by muse, mutect2, varscan2
- XPO7 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 163/383 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1174625804, COSV53020682; called by muse, mutect2, varscan2
- ZNF251 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 887/1250 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV52955693; called by muse, mutect2, varscan2
- ZNF441 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV63539919; called by muse, mutect2, varscan2
- ZNF536 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 197/500 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1291337078, COSV62819722; called by muse, mutect2, varscan2
- ZNF683 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 180/462 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs748305418, COSV62874496, COSV62874633; called by muse, varscan2
- ZNF831 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 347/600 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV64043809; called by muse, mutect2, varscan2
- ZNF91 | c.3445C>T p.L1149F | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs1316187877; called by muse, mutect2, varscan2
- AASDH | c.2594C>G p.T865S | Missense Mutation (SNP) | VAF 145/413 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ABCC12 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ACMSD | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ACSL5 | c.1537G>A p.E513K (on ENST00000354273; = p.E569K on NM_016234.3) | Missense Mutation (SNP) | VAF 126/392 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ADAM7 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ADGRF3 | c.2018G>A p.G673E (on ENST00000311519 / NM_001145168.1; = p.G474E on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 209/491 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AL160272.2 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ALDH3A2 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANAPC2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 149/369 reads (40%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 265/720 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF37 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 108/160 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2
- ARSK | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- BFAR | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 168/451 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- BTN2A1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 398/699 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- C14orf39 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1B | c.6362C>T p.S2121F | Missense Mutation (SNP) | VAF 240/601 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CACNA1I | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 147/417 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADPS2 | c.1427T>A p.I476N | Missense Mutation (SNP) | VAF 157/381 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAND2 | c.1684G>A p.D562N (on ENST00000456430 / NM_001162499.2; = p.D469N on NM_012298.3) | Missense Mutation (SNP) | VAF 168/482 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CDRT1 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 153/422 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, varscan2
- CENPA | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFAP65 | c.1381A>T p.R461* | Nonsense Mutation (SNP) | VAF 102/274 reads (37%) | called by muse, mutect2, varscan2
- CLEC4M | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 138/491 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL22A1 | c.4358G>C p.G1453A | Missense Mutation (SNP) | VAF 258/788 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A2 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 187/396 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CSMD2 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 117/319 reads (37%) | called by muse, mutect2, varscan2
- CSMD3 | c.5861G>A p.G1954E (on ENST00000297405 / NM_001363185.1; = p.G1850E on NM_052900.3) | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.5860G>A p.G1954R (on ENST00000297405 / NM_001363185.1; = p.G1850R on NM_052900.3) | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYSRT1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 192/484 reads (40%) | SIFT tolerated, low confidence (0.52); called by muse, mutect2, varscan2
- DCDC2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 215/407 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DISP3 | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 195/488 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DMBT1 | c.2267C>T p.T756I | Missense Mutation (SNP) | VAF 204/560 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNER | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 105/245 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DOCK4 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 128/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSCAML1 | c.3760C>T p.P1254S (on ENST00000321322; = p.P1194S on NM_020693.4) | Missense Mutation (SNP) | VAF 129/209 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DZIP3 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ELAPOR1 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 641/834 reads (77%) | called by muse, mutect2, varscan2
- ELOA3D | c.1110G>A p.W370* | Nonsense Mutation (SNP) | VAF 164/2262 reads (7%) | called by muse, mutect2
- EPPK1 | c.2230T>C p.Y744H | Missense Mutation (SNP) | VAF 297/1742 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F5 | c.4639G>A p.D1547N | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FATE1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 156/186 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLL1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 161/238 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FBXO42 | c.673dup p.T225Nfs*18 | Frame Shift Ins (INS) | VAF 149/413 reads (36%) | called by mutect2, pindel, varscan2
- FCGR3B | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2
- FOXD4L5 | c.941G>A p.W314* | Nonsense Mutation (SNP) | VAF 140/904 reads (15%) | called by muse, mutect2, varscan2
- GABBR2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 163/410 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GRM4 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 234/447 reads (52%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- HDGFL2 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 174/506 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- HECTD1 | c.4822_4825dup p.T1609Sfs*10 | Frame Shift Ins (INS) | VAF 115/305 reads (38%) | called by mutect2, pindel, varscan2
- HTR2C | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 222/277 reads (80%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- HTR3B | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 190/293 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV6D-21 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 153/472 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGSF1 | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 128/174 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGSF21 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 199/490 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- IGSF21 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL1RN | c.30C>A p.H10Q | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- INTU | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 158/421 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- ITSN1 | c.4103G>A p.G1368E | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH7 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KCNK18 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM2B | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 160/450 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- KIAA0319 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 302/594 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1109 | c.9149C>T p.P3050L | Missense Mutation (SNP) | VAF 166/400 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA2012 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT tolerated (0.38); called by muse, mutect2, varscan2
- KIF14 | c.4855A>G p.K1619E | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KIF5A | c.1190C>A p.T397N | Missense Mutation (SNP) | VAF 178/453 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KL | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 326/502 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCTL | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 139/416 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LYSMD1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 199/500 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LZTS1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 196/502 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED24 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 186/466 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MN1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 230/582 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MROH7 | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 512/707 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- MYCBP2 | c.749C>T p.S250F (on ENST00000357337; = p.S288F on NM_015057.5) | Missense Mutation (SNP) | VAF 411/612 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MYH15 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYRIP | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- NCOA6 | c.4786C>T p.Q1596* | Nonsense Mutation (SNP) | VAF 130/372 reads (35%) | called by muse, varscan2
- NEB | c.15355A>T p.K5119* | Nonsense Mutation (SNP) | VAF 120/286 reads (42%) | called by muse, mutect2, varscan2
- NFATC4 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 227/533 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NLRP1 | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NME8 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NONO | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 204/258 reads (79%) | called by muse, mutect2, varscan2
- NOS1 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 136/343 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K3 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OR51S1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 281/550 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ORMDL1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 171/453 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ORMDL1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 173/455 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PDZRN3 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 164/412 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.10241A>T p.N3414I | Missense Mutation (SNP) | VAF 120/440 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); called by muse, mutect2
- PLCE1 | c.3393A>T p.E1131D | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRDM6 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 250/555 reads (45%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.4892C>T p.S1631L | Missense Mutation (SNP) | VAF 161/443 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRPF8 | c.6556C>T p.P2186S | Missense Mutation (SNP) | VAF 158/489 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RALGAPA1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMBP3 | c.3635C>T p.P1212L | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- RNF150 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNF24 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RO60 | c.1049T>C p.L350S | Missense Mutation (SNP) | VAF 152/412 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SCN3A | c.4298A>C p.K1433T | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SDR42E2 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 129/196 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SF1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 228/540 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3YL1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 153/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC15A5 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A18 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC6A20 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC9A4 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMG8 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRC | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYN3 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 253/641 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SYN3 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAF5L | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 134/368 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R9 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 185/551 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- TMEM87B | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM87B | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 117/295 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TNRC18 | c.2875G>A p.G959S | Missense Mutation (SNP) | VAF 253/619 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TSC22D4 | c.1112C>A p.P371Q | Missense Mutation (SNP) | VAF 269/640 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTC19 | c.996A>T p.E332D | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- TTN | c.34267C>T p.P11423S (on ENST00000591111; = p.P12486S on NM_001267550.2) | Missense Mutation (SNP) | VAF 110/342 reads (32%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.3192G>A p.V1064= (on ENST00000393151 / NM_001346218.2; = p.V887= on NM_020818.5) | Splice Region (SNP) | VAF 118/266 reads (44%) | called by muse, mutect2, varscan2
- VAV1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 147/410 reads (36%) | called by muse, mutect2, varscan2
- VGLL3 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 213/505 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VWC2L | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZBED6 | c.2191C>T p.Q731* | Nonsense Mutation (SNP) | VAF 160/413 reads (39%) | called by muse, mutect2, varscan2
- ZFP37 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 129/328 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); called by mutect2, varscan2
- ZNF189 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZNF317 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 152/394 reads (39%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.845); called by muse, varscan2
- ZNF366 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AADACL3 | c.1128C>T p.F376= | Silent (SNP) | VAF 188/486 reads (39%) | called by muse, mutect2, varscan2
- ADGRF5 | c.3630G>A p.E1210= | Silent (SNP) | VAF 161/604 reads (27%) | called by muse, mutect2, varscan2
- AEN | c.315C>T p.P105= | Silent (SNP) | VAF 210/530 reads (40%) | called by muse, mutect2, varscan2
- AF196969.1 | c.372C>T p.I124= | Silent (SNP) | VAF 193/242 reads (80%) | catalogued as COSV99339394; called by muse, mutect2, varscan2
- AFF1 | c.2619C>T p.S873= | Silent (SNP) | VAF 160/422 reads (38%) | called by muse, mutect2, varscan2
- AGL | c.4485C>T p.S1495= | Silent (SNP) | VAF 104/297 reads (35%) | called by muse, mutect2, varscan2
- AMTN | c.342A>T p.L114= | Silent (SNP) | VAF 87/222 reads (39%) | called by muse, mutect2, varscan2
- ANK1 | c.5559G>A p.G1853= | Silent (SNP) | VAF 148/392 reads (38%) | catalogued as COSV99225326; called by muse, varscan2
- APOL3 | c.483G>A p.R161= (on ENST00000349314 / NM_145640.2; = p.R90= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 173/426 reads (41%) | called by muse, mutect2, varscan2
- AQP1 | c.354C>T p.S118= | Silent (SNP) | VAF 140/351 reads (40%) | catalogued as rs1219391889, COSV61266462; called by muse, mutect2, varscan2
- ARHGEF37 | c.681G>A p.E227= | Silent (SNP) | VAF 110/162 reads (68%) | called by muse, mutect2
- BCL10 | c.282C>T p.F94= | Silent (SNP) | VAF 156/377 reads (41%) | catalogued as COSV65353906; called by muse, mutect2, varscan2
- BNC1 | c.1395C>T p.G465= | Silent (SNP) | VAF 198/488 reads (41%) | called by muse, mutect2, varscan2
- BPIFB4 | c.75C>T p.V25= | Silent (SNP) | VAF 162/390 reads (42%) | catalogued as rs767485471; called by muse, mutect2, varscan2
- C1QTNF6 | c.195C>T p.P65= | Silent (SNP) | VAF 125/366 reads (34%) | called by muse, mutect2, varscan2
- C7 | c.1179G>A p.L393= | Silent (SNP) | VAF 182/482 reads (38%) | called by muse, mutect2
- CCDC158 | c.201C>T p.I67= | Silent (SNP) | VAF 144/409 reads (35%) | catalogued as COSV101187251; called by muse, mutect2, varscan2
- CCDC180 | c.543C>T p.F181= | Silent (SNP) | VAF 120/291 reads (41%) | catalogued as COSV63831595; called by muse, mutect2, varscan2
- CCDC63 | c.399C>T p.N133= | Silent (SNP) | VAF 99/256 reads (39%) | called by muse, mutect2, varscan2
- CD1C | c.723G>A p.R241= | Silent (SNP) | VAF 148/415 reads (36%) | catalogued as rs1443777024, COSV100939368, COSV100939494; called by muse, mutect2, varscan2
- CD3E | c.324G>A p.A108= | Silent (SNP) | VAF 123/159 reads (77%) | catalogued as rs1313464574, COSV62345112; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH6 | c.189G>A p.L63= | Silent (SNP) | VAF 122/317 reads (38%) | catalogued as COSV54066340; called by muse, mutect2, varscan2
- CHID1 | c.294C>T p.V98= | Silent (SNP) | VAF 311/556 reads (56%) | catalogued as rs765994626; called by muse, mutect2, varscan2
- CISH | c.408C>T p.S136= (on ENST00000348721 / NM_145071.4; = p.S153= on NM_013324.6) | Silent (SNP) | VAF 206/542 reads (38%) | called by muse, mutect2, varscan2
- CLCN7 | c.1587G>A p.G529= | Silent (SNP) | VAF 189/494 reads (38%) | called by muse, mutect2, varscan2
- COL4A2 | c.3360C>T p.F1120= | Silent (SNP) | VAF 122/386 reads (32%) | catalogued as rs776853058, COSV64633781; called by muse, mutect2, varscan2
- CR1 | c.4296G>A p.G1432= | Silent (SNP) | VAF 107/287 reads (37%) | catalogued as COSV65463392; called by muse, mutect2, varscan2
- CSMD2 | c.6951C>T p.I2317= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV53897759, COSV53911750; called by muse, mutect2, varscan2
- CSMD3 | c.7404C>T p.V2468= (on ENST00000297405 / NM_001363185.1; = p.V2364= on NM_052900.3) | Silent (SNP) | VAF 128/407 reads (31%) | catalogued as COSV99845448; called by muse, mutect2, varscan2
- CYP2D7 | c.492C>T p.F164= | Silent (SNP) | VAF 296/706 reads (42%) | catalogued as rs1265649425; called by muse, mutect2
- CYP2D7 | c.318C>T p.I106= | Silent (SNP) | VAF 159/427 reads (37%) | called by muse, mutect2, varscan2
- DACH1 | c.1935G>A p.L645= (on ENST00000619232 / NM_001366712.1; = p.L391= on NM_004392.6) | Silent (SNP) | VAF 136/688 reads (20%) | called by muse, varscan2
- DNAH6 | c.11302T>C p.L3768= | Silent (SNP) | VAF 96/225 reads (43%) | called by muse, mutect2, varscan2
- DNMT3B | c.711C>T p.S237= | Silent (SNP) | VAF 201/482 reads (42%) | called by muse, mutect2, varscan2
- DSCAM | c.4347C>T p.F1449= | Silent (SNP) | VAF 103/344 reads (30%) | called by muse, mutect2, varscan2
- DSP | c.6630C>T p.F2210= | Silent (SNP) | VAF 113/391 reads (29%) | called by muse, mutect2, varscan2
- DUS2 | c.1329G>A p.E443= | Silent (SNP) | VAF 178/606 reads (29%) | catalogued as rs1217473998; called by muse, mutect2
- ERC2 | c.1032G>A p.V344= | Silent (SNP) | VAF 151/367 reads (41%) | catalogued as rs1031350431, COSV55611741; called by muse, mutect2, varscan2
- F11 | c.834C>T p.F278= | Silent (SNP) | VAF 115/294 reads (39%) | called by muse, mutect2, varscan2
- F11R | c.891C>T p.F297= | Silent (SNP) | VAF 140/365 reads (38%) | called by muse, mutect2, varscan2
- FAM83F | c.1494G>A p.V498= | Silent (SNP) | VAF 164/392 reads (42%) | catalogued as rs1179414275, COSV60999441; called by muse, mutect2, varscan2
- FBLL1 | c.519C>T p.S173= | Silent (SNP) | VAF 162/239 reads (68%) | called by muse, mutect2, varscan2
- FREM3 | c.5508G>A p.Q1836= | Silent (SNP) | VAF 136/350 reads (39%) | called by muse, mutect2, varscan2
- GAS2L3 | c.2055C>T p.V685= | Silent (SNP) | VAF 99/229 reads (43%) | catalogued as rs1466690135; called by muse, mutect2, varscan2
- GJA1 | c.588G>A p.V196= | Silent (SNP) | VAF 190/296 reads (64%) | catalogued as rs1192613862; called by muse, mutect2, varscan2
- HNF1B | c.726C>T p.S242= | Silent (SNP) | VAF 256/621 reads (41%) | called by muse, mutect2, varscan2
- HNF1B | c.324G>A p.A108= | Silent (SNP) | VAF 179/424 reads (42%) | called by muse, mutect2, varscan2
- HSP90B1 | c.774C>T p.Y258= | Silent (SNP) | VAF 81/218 reads (37%) | called by muse, mutect2, varscan2
- IGDCC3 | c.1593C>T p.V531= | Silent (SNP) | VAF 199/503 reads (40%) | called by muse, mutect2, varscan2
- IGKV2D-30 | c.294G>A p.L98= | Silent (SNP) | VAF 114/311 reads (37%) | called by muse, mutect2, varscan2
- INSIG1 | c.321C>T p.I107= | Silent (SNP) | VAF 190/505 reads (38%) | called by muse, mutect2, varscan2
- ITK | c.1182G>A p.R394= | Silent (SNP) | VAF 159/226 reads (70%) | called by muse, mutect2, varscan2
- KIAA1109 | c.7353C>T p.I2451= | Silent (SNP) | VAF 132/331 reads (40%) | called by muse, mutect2, varscan2
- KIF2B | c.462G>A p.Q154= | Silent (SNP) | VAF 134/352 reads (38%) | catalogued as rs1438325673; called by muse, varscan2
- KPNA7 | c.33G>A p.R11= | Silent (SNP) | VAF 143/359 reads (40%) | called by muse, mutect2, varscan2
- MATK | c.472C>T p.L158= (on ENST00000310132 / NM_139355.3; = p.L159= on NM_002378.4) | Silent (SNP) | VAF 211/542 reads (39%) | catalogued as COSV100036049; called by muse, mutect2, varscan2
- MC3R | c.294C>T p.I98= | Silent (SNP) | VAF 330/609 reads (54%) | catalogued as rs748895410, COSV54763185; called by muse, mutect2, varscan2
- MTHFS | c.543C>T p.L181= | Silent (SNP) | VAF 126/342 reads (37%) | called by muse, mutect2, varscan2
- MXRA5 | c.7443C>T p.P2481= | Silent (SNP) | VAF 199/249 reads (80%) | catalogued as rs773264166, COSV54222567; called by muse, mutect2, varscan2
- OR11H6 | c.459C>T p.I153= | Silent (SNP) | VAF 175/405 reads (43%) | catalogued as rs1222460608, COSV59644560; called by muse, mutect2, varscan2
- OR13C8 | c.429C>T p.A143= | Silent (SNP) | VAF 173/429 reads (40%) | catalogued as rs758881928; called by muse, mutect2, varscan2
- OR14K1 | c.474A>G p.T158= | Silent (SNP) | VAF 120/280 reads (43%) | catalogued as COSV99315254; called by muse, mutect2, varscan2
- OR2AT4 | c.294C>T p.S98= | Silent (SNP) | VAF 211/311 reads (68%) | called by muse, mutect2, varscan2
- OR2C3 | c.123G>A p.L41= | Silent (SNP) | VAF 178/438 reads (41%) | called by muse, mutect2, varscan2
- OR4C12 | c.654C>T p.I218= | Silent (SNP) | VAF 138/575 reads (24%) | catalogued as COSV58860599; called by muse, mutect2, varscan2
- OR4X1 | c.486C>T p.F162= | Silent (SNP) | VAF 293/552 reads (53%) | catalogued as COSV60722215; called by muse, mutect2, varscan2
- OR5B3 | c.30C>T p.F10= | Silent (SNP) | VAF 234/435 reads (54%) | catalogued as rs767629637, COSV100511923; called by muse, mutect2, varscan2
- OR5W2 | c.288C>T p.G96= | Silent (SNP) | VAF 124/469 reads (26%) | catalogued as rs1354387894, COSV60617617; called by muse, mutect2, varscan2
- OR8K3 | c.405C>T p.I135= | Silent (SNP) | VAF 185/637 reads (29%) | called by muse, mutect2, varscan2
- P2RX1 | c.240C>T p.L80= | Silent (SNP) | VAF 208/513 reads (41%) | catalogued as rs755120606; called by muse, mutect2, varscan2
- PABPC4L | c.945A>C p.S315= | Silent (SNP) | VAF 125/319 reads (39%) | called by muse, mutect2, varscan2
- PCDHB3 | c.558G>A p.R186= | Silent (SNP) | VAF 154/238 reads (65%) | catalogued as rs1554272217; called by muse, mutect2, varscan2
- PCLO | c.8979C>T p.S2993= | Silent (SNP) | VAF 156/406 reads (38%) | catalogued as rs1482008986; called by muse, mutect2, varscan2
- PISD | c.507C>T p.F169= (on ENST00000439502 / NM_001326412.1; = p.F135= on NM_014338.3) | Silent (SNP) | VAF 168/441 reads (38%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.489C>T p.F163= | Silent (SNP) | VAF 290/774 reads (37%) | catalogued as COSV69599507; called by muse, mutect2
- PPARGC1B | c.1431G>A p.R477= | Silent (SNP) | VAF 238/354 reads (67%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.126C>T p.F42= | Silent (SNP) | VAF 272/664 reads (41%) | catalogued as rs766696172, COSV101463166; called by muse, mutect2, varscan2
- PRR36 | c.1071C>T p.P357= | Silent (SNP) | VAF 240/616 reads (39%) | called by muse, mutect2, varscan2
- PRRG1 | c.465C>T p.R155= | Silent (SNP) | VAF 118/152 reads (78%) | called by muse, mutect2, varscan2
- QSER1 | c.3300A>G p.K1100= (on ENST00000399302; = p.K1229= on NM_001076786.3) | Silent (SNP) | VAF 136/565 reads (24%) | called by muse, mutect2, varscan2
- RAB37 | c.162C>T p.F54= | Silent (SNP) | VAF 140/389 reads (36%) | catalogued as rs1253052980; called by muse, mutect2, varscan2
- RASSF6 | c.153C>T p.F51= (on ENST00000342081 / NM_201431.2; = p.F19= on NM_177532.5) | Silent (SNP) | VAF 93/209 reads (44%) | catalogued as COSV56720664; called by muse, mutect2, varscan2
- RNF213 | c.4167C>T p.R1389= | Silent (SNP) | VAF 100/274 reads (36%) | called by muse, mutect2, varscan2
- RNF24 | c.396G>A p.Q132= | Silent (SNP) | VAF 161/431 reads (37%) | called by muse, mutect2, varscan2
- RNF34 | c.273C>T p.V91= | Silent (SNP) | VAF 138/332 reads (42%) | catalogued as COSV63443248; called by muse, mutect2, varscan2
- SCN2A | c.300C>T p.I100= | Silent (SNP) | VAF 109/265 reads (41%) | called by muse, mutect2, varscan2
- SETD5 | c.969C>T p.P323= | Silent (SNP) | VAF 112/307 reads (36%) | catalogued as rs570367798; called by muse, mutect2, varscan2
- SF1 | c.1710C>T p.P570= | Silent (SNP) | VAF 235/547 reads (43%) | catalogued as rs750067656; called by muse, mutect2, varscan2
- SIRPD | c.537C>T p.F179= | Silent (SNP) | VAF 174/429 reads (41%) | catalogued as rs758873532, COSV67547225; called by muse, mutect2, varscan2
- SLC17A3 | c.834C>T p.F278= | Silent (SNP) | VAF 127/397 reads (32%) | catalogued as COSV57759814; called by muse, mutect2, varscan2
- SLC22A13 | c.1245C>T p.P415= | Silent (SNP) | VAF 95/263 reads (36%) | catalogued as rs779792115, COSV100314683; called by muse, mutect2, varscan2
- SLC34A3 | c.6G>A p.P2= | Silent (SNP) | VAF 126/342 reads (37%) | catalogued as rs771812828; called by muse, mutect2, varscan2
- SLC5A1 | c.1467G>A p.L489= | Silent (SNP) | VAF 98/279 reads (35%) | called by muse, mutect2, varscan2
- SLC7A2 | c.339C>T p.F113= (on ENST00000494857 / NM_001370338.1; = p.F153= on NM_003046.6) | Silent (SNP) | VAF 128/359 reads (36%) | called by muse, mutect2, varscan2
- SSC5D | c.2856C>T p.T952= | Silent (SNP) | VAF 213/501 reads (43%) | catalogued as rs185597506; called by muse, mutect2, varscan2
- STK25 | c.411C>T p.I137= | Silent (SNP) | VAF 145/353 reads (41%) | catalogued as rs1439696603, COSV57263386; called by muse, mutect2, varscan2
- SYNGR1 | c.351C>T p.F117= | Silent (SNP) | VAF 176/430 reads (41%) | catalogued as COSV53368131; called by muse, mutect2, varscan2
- TAF1L | c.3447G>A p.R1149= | Silent (SNP) | VAF 196/477 reads (41%) | catalogued as COSV54271346; called by muse, mutect2, varscan2
- TAF5L | c.1050C>T p.F350= | Silent (SNP) | VAF 137/371 reads (37%) | called by muse, mutect2, varscan2
- TMC3 | c.3090G>A p.G1030= | Silent (SNP) | VAF 165/396 reads (42%) | catalogued as rs368578804, COSV63924709; called by muse, mutect2, varscan2
- TNRC18 | c.2874G>A p.A958= | Silent (SNP) | VAF 253/614 reads (41%) | catalogued as rs1308482939; called by muse, mutect2, varscan2
- TPK1 | c.270C>T p.L90= | Silent (SNP) | VAF 80/273 reads (29%) | catalogued as rs973031491; called by muse, mutect2, varscan2
- TRAV25 | c.264G>A p.K88= | Silent (SNP) | VAF 114/301 reads (38%) | catalogued as rs1423978927; called by muse, mutect2, varscan2
- UBE2E2 | c.237C>T p.P79= | Silent (SNP) | VAF 120/292 reads (41%) | catalogued as rs377278728; called by muse, mutect2, varscan2
- USP17L2 | c.219G>A p.R73= | Silent (SNP) | VAF 239/1193 reads (20%) | catalogued as rs760816302, COSV61555712; called by muse, mutect2, varscan2
- USP26 | c.954G>A p.S318= | Silent (SNP) | VAF 188/231 reads (81%) | catalogued as rs779378931; called by muse, mutect2, varscan2
- ZNF317 | c.1722G>A p.R574= | Silent (SNP) | VAF 148/394 reads (38%) | called by muse, varscan2
- ZNF585A | c.1545C>T p.I515= (on ENST00000292841 / NM_001288800.2; = p.I460= on NM_152655.3) | Silent (SNP) | VAF 121/335 reads (36%) | called by muse, mutect2, varscan2
- ZNF627 | c.684T>C p.C228= | Silent (SNP) | VAF 162/389 reads (42%) | called by muse, mutect2, varscan2
- ZNF652 | c.960C>T p.I320= | Silent (SNP) | VAF 121/370 reads (33%) | catalogued as COSV62946634; called by muse, mutect2
- ZNF683 | c.549G>A p.K183= | Silent (SNP) | VAF 198/485 reads (41%) | called by muse, mutect2, varscan2
- ZNF735 | c.258C>T p.H86= | Silent (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1166G>A | Intron (SNP) | VAF 175/457 reads (38%) | catalogued as COSV63754980; called by muse, mutect2, varscan2
- BRMS1 | c.*135C>T | 3'UTR (SNP) | VAF 197/295 reads (67%) | called by muse, mutect2, varscan2
- C7orf25 | c.-145C>T | 5'UTR (SNP) | VAF 187/458 reads (41%) | catalogued as COSV56237264; called by muse, mutect2, varscan2
- FCRL6 | c.-2C>T | 5'UTR (SNP) | VAF 117/309 reads (38%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1663G>A | Intron (SNP) | VAF 213/544 reads (39%) | catalogued as rs991441143; called by muse, varscan2
- LIMCH1 | c.936-6075G>A | Intron (SNP) | VAF 116/310 reads (37%) | catalogued as rs1000280541; called by muse, mutect2, varscan2
- MGAM | c.4619-10057C>T | Intron (SNP) | VAF 120/161 reads (75%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8767C>T | Intron (SNP) | VAF 117/146 reads (80%) | catalogued as rs776287872; called by muse, mutect2, varscan2
- PCLO | c.14791+1713G>A | Intron (SNP) | VAF 142/355 reads (40%) | called by muse, mutect2, varscan2
- STYK1 | c.*57C>T | 3'UTR (SNP) | VAF 160/431 reads (37%) | called by muse, mutect2, varscan2
- UNC13B | c.1168-13520C>T | Intron (SNP) | VAF 104/274 reads (38%) | called by muse, mutect2, varscan2
